Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4441, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4441-01A (Primary Tumor).

Diagnosis/diagnoses:

Total gastrectomy preparation with an ulcerated gastric carcinoma located in the middle of the stomach on the side of the greater curvature, encroaching on the anterior and posterior wall of the stomach to within a maximum of 5 cm of the oral and 11.5 cm of the aboral resection margin, with a maximum diameter of 8 cm and characterized histologically as a moderately differentiated adenocarcinoma (gastric carcinoma of the intestinal type). Invasive tumor spread within all the parietal layers of the stomach as far as the level of the serosa and directly under the serosa, as well as the perigastric fatty tissue with signs of lymph vessel spread in the tumor margin area.

Oral and aboral resection margin and also greater omentum tumor-free.

Fourteen of sixteen lymph nodes with gastric carcinoma metastases growing over the capsule partly growing over the capsule.

Mucosa of the antrum with non-florid, low to medium-grade chronic gastritis, foveolar hyperplasia, foci of intestinal metaplasia and partial atrophy of the mucosa. No evidence of *Helicobacter pylori*.

Tumor stage thus pT2b pN2 (14/16)

Source: NCI Genomic Data Commons file bf9fc3bc-f846-482a-a131-5a10dd82db08 (TCGA-CG-4441.36EB6C24-C49A-4812-B3CF-DD491C4EFB59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).